Somatic mutation profile of tumor specimen TCGA-EO-A22R-01A (aliquot TCGA-EO-A22R-01A-11D-A18P-09) from TCGA case TCGA-EO-A22R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 56.4 years (20,604 days).
Specimen TCGA-EO-A22R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9fe21d7-b455-4c03-b3d9-14ee75b9f625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A22R-11A (Solid Tissue Normal), aliquot TCGA-EO-A22R-11A-11D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a57f209-4e45-4ded-ae72-c86b5224e082

The open-access MAF lists 15,198 somatic variants for this specimen: 11,403 protein-altering or splice-affecting, 3,407 silent, 388 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10,308, Silent 3,407, Nonsense Mutation 757, Splice Site 152, Intron 151, RNA 116, Splice Region 98, Frame Shift Ins 50, 3'UTR 45, 5'Flank 29, 5'UTR 26, Frame Shift Del 23.

Variants (750 of 15,198; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs1057517908, COSV59247325; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTA1 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs121909522, CM034500, CM992121, CM992122, COSV64203141; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as rs886041128, CM003405; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.6232C>T p.R2078* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as rs199422168, CM095684, COSV54125033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.2773C>T p.R925* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs386833748, CM096680, COSV101052756; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs121964878, CM034217, COSV55730231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH23 | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs866435331, CM105103; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP89 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as COSV59867749; called by muse, mutect2, varscan2
- CHM | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs886041179, CM970301; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs267606739, CM001967, COSV60697817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNNM4 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs75267011, CM090746; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2228G>A p.G743D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886166, CM990398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COQ8A | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755933881, CM1415053, COSV100825626; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP11A1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs776056840, CM1210479, COSV99166146; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDC | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853207, CM984684; ClinVar: pathogenic; called by muse, varscan2
- DEPDC5 | c.2386C>T p.R796* (on ENST00000400246; = p.R865* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as rs578185749, CM146221, COSV99835340; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPCAM | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs397514661, CM100125; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESRRB | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1060499794; ClinVar: pathogenic; called by muse, varscan2
- F5 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as rs757953549, CM980661, COSV100888970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- GFM1 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs863224032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLA | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894834, CM051064, CM920311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD11B1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs387907168, CM111740, COSV54828579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IFT140 | c.2278C>T p.R760* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as rs1555486629, CM136695, COSV54153789; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IGHMBP2 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as rs773242930, CM041024; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ4 | c.823T>C p.W275R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797044968, CM148036; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.13645C>T p.R4549C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51276981, COSV51294405; called by muse, mutect2, varscan2
- LYST | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs80338643, CM970310; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3013C>T p.R1005* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs63750563, CM053329, COSV99315067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.3157C>T p.R1053W | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880903, COSV100806383; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs199475626, CM010956, CM971128; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- PCDH15 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs137853003, CM033656; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>C p.V411L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57676103, COSV57677068, COSV57683938; called by muse, mutect2, varscan2
- POLG | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs121918056, CM030935; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP1CB | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as rs886037955; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PPP2CA | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs148071386, COSV51538274; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PPP2R1A | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 36/92 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205227, CM153572, COSV59042121; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRPH2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs61755787, CM951117, COSV57837952; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, varscan2
- RS1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs281865362, CM1110585, CM1212041, CM971323, COSV66106094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs121912668, CM941286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SRPX2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1556013503, COSV100883977, COSV65933194; ClinVar: likely pathogenic; called by muse, varscan2
- TBX2 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs1555877071; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs121918719, CM951204, COSV52862374; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TNNI3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs397516349, CM971497, COSV52572698; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TPM3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs121964852, CM072092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.99169C>T p.R33057* (on ENST00000591111; = p.R25633* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as rs727504184, CM144268, COSV100587703; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- VPS33B | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs121434385, CM041097; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- A1CF | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1564500563, COSV104391212, COSV50968866; called by muse, varscan2
- A1CF | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51004433; called by muse, varscan2
- A2ML1 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as rs1228315173; called by muse, mutect2, varscan2
- A2ML1 | c.3466C>A p.L1156I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55289840; called by muse, mutect2, varscan2
- AAAS | c.1161G>T p.Q387H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52934615; called by muse, mutect2, varscan2
- AADACL2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs763997055, COSV100735848; called by muse, mutect2, varscan2
- AARS1 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs868080749, COSV55747541; called by muse, mutect2, varscan2
- AARS2 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as rs1227211099, COSV55113600; called by muse, mutect2, varscan2
- AASDH | c.2788G>A p.V930I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs771373118, COSV52705711; called by muse, mutect2, varscan2
- AASDH | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs188668680, COSV52711592; called by muse, mutect2, varscan2
- AASDHPPT | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99593405; called by muse, mutect2, varscan2
- AATF | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs754559104; called by muse, mutect2, varscan2
- AATF | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs754019125; called by muse, mutect2, varscan2
- AATK | c.737G>A p.R246H (on ENST00000326724 / NM_001080395.3; = p.R143H on NM_004920.2) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs771152854, COSV100452730; called by muse, mutect2, varscan2
- ABCA1 | c.3826G>A p.G1276R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs755256833; called by muse, mutect2, varscan2
- ABCA1 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1212597294; called by muse, mutect2, varscan2
- ABCA10 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV104393371; called by muse, mutect2, varscan2
- ABCA12 | c.4415G>A p.R1472H (on ENST00000272895 / NM_173076.3; = p.R1154H on NM_015657.3) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs377470191, COSV55951021; called by muse, mutect2, varscan2
- ABCA12 | c.1868A>G p.N623S (on ENST00000272895 / NM_173076.3; = p.N305S on NM_015657.3) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753830799; called by muse, mutect2, varscan2
- ABCA12 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55954066; called by muse, mutect2, varscan2
- ABCA13 | c.2868G>T p.K956N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as rs776360790; called by muse, mutect2, varscan2
- ABCA13 | c.13355G>A p.S4452N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.777); catalogued as rs1378561510; called by muse, mutect2, varscan2
- ABCA4 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs891533398; called by muse, mutect2, varscan2
- ABCA4 | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs886039297, CM042256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.4765G>T p.A1589S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs910917944; called by muse, mutect2, varscan2
- ABCA5 | c.4244G>A p.R1415Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1420166075, COSV101201274; called by muse, mutect2, varscan2
- ABCA5 | c.128dup p.L43Ffs*8 | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | catalogued as rs751512043; called by mutect2, varscan2
- ABCA6 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV52636877; called by muse, mutect2, varscan2
- ABCA6 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs138416476, COSV52637314; called by muse, varscan2
- ABCA6 | c.2914C>T p.H972Y | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs781711966; called by muse, varscan2
- ABCA8 | c.3937G>A p.G1313S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371505100; called by muse, mutect2, varscan2
- ABCA9 | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372952180; called by muse, mutect2, varscan2
- ABCB1 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139820108; called by muse, mutect2, varscan2
- ABCB1 | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as rs1470273650, COSV99711973; called by muse, mutect2, varscan2
- ABCB11 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs776561679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB11 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV55585744; called by muse, mutect2, varscan2
- ABCB4 | c.3493G>A p.E1165K (on ENST00000265723 / NM_018849.3; = p.E1158K on NM_000443.4) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs767538466, COSV55932490; called by muse, mutect2, varscan2
- ABCB4 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs147134978, CM075949; called by muse, mutect2, varscan2
- ABCB4 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514620, CM082462, CM159639; called by muse, mutect2, varscan2
- ABCB4 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs1316774479; called by muse, mutect2, varscan2
- ABCB6 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs200246711; called by muse, varscan2
- ABCB8 | c.420T>A p.F140L (on ENST00000297504 / NM_001282291.2; = p.F123L on NM_007188.5) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV99873671; called by muse, mutect2, varscan2
- ABCB9 | c.2171A>G p.H724R (on ENST00000280560 / NM_019625.4; = p.H681R on NM_019624.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99757863; called by muse, mutect2, varscan2
- ABCC1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60682531; called by muse, mutect2, varscan2
- ABCC1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs758046256, COSV60681096; called by muse, mutect2, varscan2
- ABCC11 | c.3636G>T p.E1212D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV62326304; called by muse, mutect2, varscan2
- ABCC11 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs199620156, COSV62322013; called by muse, mutect2, varscan2
- ABCC3 | c.2948C>T p.A983V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); catalogued as rs756988794, COSV53317514; called by muse, mutect2, varscan2
- ABCC4 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs781506182; called by muse, varscan2
- ABCC5 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV55593362; called by muse, mutect2, varscan2
- ABCC5 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs781461232, COSV55595828, COSV55596607; called by muse, mutect2, varscan2
- ABCC8 | c.4252C>T p.R1418C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468762603, CM107095; called by muse, mutect2, varscan2
- ABCC9 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV53966044; called by muse, mutect2, varscan2
- ABCD1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as rs1255903649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs782611445; called by muse, mutect2, varscan2
- ABCD3 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs1557691806, COSV64642599; called by muse, mutect2, varscan2
- ABCG1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs959974308, COSV59209161; called by muse, mutect2, varscan2
- ABCG1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1326186208; called by muse, mutect2, varscan2
- ABCG5 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.12); catalogued as rs747481748, COSV53210126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD1 | c.991T>C p.F331L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs757264284; called by muse, mutect2, varscan2
- ABHD10 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as rs1381316613, COSV56324640; called by muse, mutect2, varscan2
- ABHD12B | c.620G>A p.G207D (on ENST00000337334 / NM_001206673.2; = p.G130D on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV61569279; called by muse, mutect2, varscan2
- ABHD2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61772877; called by muse, mutect2, varscan2
- ABL1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1314838108; called by muse, varscan2
- ABLIM2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1184643633, COSV104405464; called by muse, mutect2, varscan2
- ABTB2 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs746167793; called by muse, varscan2
- AC011448.1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs758935454, COSV99364153, COSV99364527; called by muse, mutect2, varscan2
- AC013477.1 | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs558905999, COSV53654513, COSV53655900; called by muse, mutect2, varscan2
- AC013489.1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs373214566, COSV51549905; called by muse, mutect2, varscan2
- AC131160.1 | c.1141T>G p.F381V | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV59414871; called by muse, mutect2, varscan2
- AC131160.1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV57701732; called by muse, mutect2, varscan2
- AC136428.1 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV71169142; called by muse, mutect2, varscan2
- ACACB | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361682154, COSV100622930; called by muse, mutect2, varscan2
- ACACB | c.4469G>A p.R1490H | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200016239; called by muse, varscan2
- ACACB | c.5681C>T p.T1894M | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs772701854, COSV58141531; called by muse, mutect2, varscan2
- ACAD10 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1469335376; called by muse, mutect2, varscan2
- ACADL | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs546101555; called by muse, mutect2, varscan2
- ACADL | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs375084422, CM112334, COSV52052059, COSV52052222; called by muse, mutect2, varscan2
- ACADVL | c.480C>T p.Y160= | Splice Region (SNP) | VAF 40/104 reads (38%) | catalogued as rs371910495; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACAN | c.4752G>T p.E1584D | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.914); catalogued as COSV61365463; called by muse, mutect2, varscan2
- ACCS | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs758423933, COSV55457716; called by muse, mutect2, varscan2
- ACCSL | c.729C>A p.C243* | Nonsense Mutation (SNP) | VAF 58/144 reads (40%) | catalogued as COSV101122330; called by muse, mutect2, varscan2
- ACER1 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV56836156, COSV56836524; called by muse, mutect2, varscan2
- ACIN1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV52980981; called by muse, mutect2, varscan2
- ACO2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as rs147361669, COSV99347680; called by muse, mutect2, varscan2
- ACOT11 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs751281591; called by muse, mutect2, varscan2
- ACOT13 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57765444; called by muse, mutect2, varscan2
- ACOT7 | c.965G>A p.R322H (on ENST00000377855 / NM_181864.3; = p.R312H on NM_007274.4) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs746127296, COSV64115065; called by muse, mutect2, varscan2
- ACP4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs765260771; called by muse, mutect2, varscan2
- ACP5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs774428695, COSV54537552; called by muse, mutect2, varscan2
- ACP7 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs770475104; called by muse, mutect2, varscan2
- ACSBG1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs774668709, COSV51906562; called by muse, mutect2, varscan2
- ACSF2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as rs749125979; called by muse, mutect2, varscan2
- ACSL5 | c.570G>T p.K190N (on ENST00000354273; = p.K246N on NM_016234.3) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287081923, COSV61128656; called by muse, mutect2, varscan2
- ACSL5 | c.1058G>A p.R353Q (on ENST00000354273; = p.R409Q on NM_016234.3) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759733603, COSV100634804; called by muse, mutect2, varscan2
- ACSL6 | c.1471C>T p.L491F (on ENST00000379240; = p.L516F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757889354; called by mutect2, varscan2
- ACSM1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | catalogued as COSV54636612; called by muse, mutect2, varscan2
- ACSM4 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV68067432; called by muse, mutect2
- ACSS3 | c.444A>C p.E148D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV54095839; called by muse, mutect2, varscan2
- ACTL10 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs370919410, COSV55777051; called by muse, mutect2, varscan2
- ACTN3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.729); catalogued as rs1290257280, COSV101557814; called by muse, mutect2, varscan2
- ACTN3 | c.1883G>A p.C628Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs867857611; called by muse, mutect2, varscan2
- ACY3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs200546996, COSV99662910; called by muse, mutect2, varscan2
- ADAM22 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55985464; called by muse, mutect2, varscan2
- ADAM23 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52212968; called by muse, mutect2, varscan2
- ADAMTS1 | c.2791dup p.R931Kfs*9 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | catalogued as rs754295488; called by mutect2, varscan2
- ADAMTS1 | c.2294G>A p.G765D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as rs1157338374; called by muse, mutect2, varscan2
- ADAMTS1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs770017773, COSV53170046; called by muse, varscan2
- ADAMTS12 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs752972657, COSV61259911; called by muse, mutect2, varscan2
- ADAMTS14 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as rs372668477; called by muse, mutect2, varscan2
- ADAMTS14 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750200846, COSV64600799; called by muse, mutect2, varscan2
- ADAMTS14 | c.3092G>A p.R1031K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100941290; called by muse, mutect2, varscan2
- ADAMTS15 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs780628863; called by muse, mutect2, varscan2
- ADAMTS2 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs200806292; called by muse, mutect2, varscan2
- ADAMTS2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs546681307, COSV51079230; called by muse, varscan2
- ADAMTS20 | c.2010G>T p.K670N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67125638; called by muse, mutect2, varscan2
- ADAMTS3 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV54401352; called by muse, mutect2, varscan2
- ADAMTS7 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767569244, COSV101182990; called by muse, mutect2, varscan2
- ADAMTS7 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs866830947; called by muse, mutect2, varscan2
- ADAMTS9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759664813, COSV55774765; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV65887428; called by muse, mutect2, varscan2
- ADAP2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs377598564; called by muse, varscan2
- ADAP2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs199636975; called by muse, varscan2
- ADARB1 | c.2138C>T p.A713V (on ENST00000360697 / NM_001346687.2; = p.A673V on NM_001112.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs748901930, COSV62343279; called by muse, mutect2, varscan2
- ADCY10 | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.183); catalogued as COSV100896865; called by muse, mutect2, varscan2
- ADCY2 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57875044; called by muse, varscan2
- ADCY2 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1310622653, COSV57890905; called by muse, mutect2, varscan2
- ADCY2 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs750935010, COSV57887908; called by muse, mutect2, varscan2
- ADCY3 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1466209850, COSV53169052; called by muse, mutect2, varscan2
- ADCY5 | c.2830G>A p.V944M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as rs1339168382; called by muse, mutect2, varscan2
- ADCY7 | c.1369-1G>T p.X457_splice | Splice Site (SNP) | VAF 15/29 reads (52%) | catalogued as COSV54269778; called by muse, mutect2, varscan2
- ADCY7 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54265344; called by muse, mutect2, varscan2
- ADCY9 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773073326, COSV53571316; called by muse, varscan2
- ADCY9 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1306562915; called by muse, mutect2, varscan2
- ADCY9 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53573952; called by muse, mutect2, varscan2
- ADD2 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV52460452; called by muse, mutect2, varscan2
- ADD2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs781815708; called by muse, mutect2, varscan2
- ADGRA1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs377602892; called by muse, varscan2
- ADGRA2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754053108, COSV59444629, COSV59447231; called by muse, mutect2, varscan2
- ADGRB1 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752785041, COSV100029884, COSV60096304; called by muse, mutect2, varscan2
- ADGRB2 | c.4322G>A p.R1441H | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1451727282, COSV57071564; called by muse, mutect2, varscan2
- ADGRB2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs902839902; called by muse, mutect2, varscan2
- ADGRB3 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65380723; called by muse, varscan2
- ADGRB3 | c.4269C>A p.D1423E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs760144348; called by muse, mutect2, varscan2
- ADGRD1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs148017957; called by muse, mutect2, varscan2
- ADGRE1 | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs1173223315, COSV51672122; called by muse, mutect2, varscan2
- ADGRE1 | c.2077A>G p.M693V | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV51674619; called by muse, mutect2, varscan2
- ADGRG2 | c.1828G>A p.G610S (on ENST00000379869 / NM_001079858.3; = p.G607S on NM_005756.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763811103; called by muse, varscan2
- ADGRG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs138853777; called by muse, mutect2, varscan2
- ADGRG4 | c.6572C>T p.A2191V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as COSV104381511; called by muse, mutect2, varscan2
- ADGRG7 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV56300428; called by muse, mutect2, varscan2
- ADGRL2 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229743701, COSV54680433; called by muse, mutect2
- ADGRL2 | c.3124G>A p.A1042T (on ENST00000370717 / NM_001366005.1; = p.A1029T on NM_012302.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.182); catalogued as rs373385024; called by muse, mutect2, varscan2
- ADGRL2 | c.3379C>T p.R1127C (on ENST00000370717 / NM_001366005.1; = p.R1114C on NM_012302.4) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775087345, COSV54673990, COSV54685771; called by muse, mutect2, varscan2
- ADGRL2 | c.3404G>A p.R1135H (on ENST00000370717 / NM_001366005.1; = p.R1122H on NM_012302.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779502306, COSV54680274, COSV99591631; called by muse, mutect2, varscan2
- ADGRL3 | c.1178C>A p.S393Y (on ENST00000506720 / NM_001322402.2; = p.S325Y on NM_015236.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72266199; called by muse, mutect2, varscan2
- ADGRL4 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.19); catalogued as rs1244238734; called by muse, varscan2
- ADGRL4 | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100875921; called by muse, varscan2
- ADGRV1 | c.14621C>G p.S4874C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs748803919; called by muse, mutect2, varscan2
- ADH1C | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs750873906, COSV72463652; called by muse, mutect2, varscan2
- ADH4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs370233244, COSV55501144; called by muse, mutect2, varscan2
- ADHFE1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as rs751588736; called by muse, mutect2, varscan2
- ADI1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs764517683, COSV59376670; called by muse, mutect2, varscan2
- ADIPOR1 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1196631555, COSV61851549; called by muse, mutect2, varscan2
- ADNP2 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs1306668330; called by muse, mutect2, varscan2
- ADNP2 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100081001, COSV51541191; called by muse, mutect2, varscan2
- ADORA2B | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV58481512; called by muse, mutect2, varscan2
- ADPGK | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs752942617, COSV61173705; called by muse, mutect2, varscan2
- ADRA1A | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as rs752263648, COSV52356426; called by muse, mutect2, varscan2
- ADRA2A | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54528628; called by muse, mutect2, varscan2
- ADRA2B | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337347; called by muse, mutect2, varscan2
- ADRB3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773500249; called by muse, mutect2, varscan2
- ADSL | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746501563, CM001052, CM082479, COSV99341979; called by muse, mutect2, varscan2
- ADSS1 | c.1323C>A p.V441= | Splice Region (SNP) | VAF 31/74 reads (42%) | catalogued as rs750886513; called by muse, mutect2, varscan2
- AEN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763210791; called by muse, mutect2, varscan2
- AFF1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs774013746, COSV57121324; called by muse, mutect2, varscan2
- AFF1 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs368760847, COSV100320293; called by muse, mutect2, varscan2
- AFF2 | c.3819C>A p.F1273L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53989173; called by muse, mutect2, varscan2
- AFF3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs1330459783; called by muse, mutect2, varscan2
- AFG3L2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs757484600; called by muse, mutect2, varscan2
- AFMID | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs576783336, COSV56961441; called by muse, mutect2, varscan2
- AFTPH | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53216188; called by muse, mutect2, varscan2
- AGA | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1203389089; called by muse, mutect2, varscan2
- AGAP2 | c.1861C>T p.R621W (on ENST00000547588 / NM_001122772.2; = p.R285W on NM_014770.4) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759142223, COSV99223773; called by muse, mutect2, varscan2
- AGAP2 | c.1189G>T p.E397* (on ENST00000547588 / NM_001122772.2; = p.E61* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs1555199429; called by muse, mutect2, varscan2
- AGAP3 | c.1756G>A p.E586K (on ENST00000622464; = p.E622K on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs904527221; called by muse, mutect2, varscan2
- AGGF1 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs371187007; called by mutect2, varscan2
- AGL | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs375531470; called by muse, mutect2, varscan2
- AGMO | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751893917, COSV61111511; called by muse, mutect2, varscan2
- AGMO | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as rs746980089, COSV61124504; called by muse, mutect2
- AGO1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1170596078; called by muse, mutect2, varscan2
- AGO1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595188; called by muse, mutect2, varscan2
- AHCTF1 | c.3064C>T p.R1022W (on ENST00000366508; = p.R996W on NM_015446.5) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs781636571; called by muse, varscan2
- AHCY | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1021875336; called by muse, mutect2, varscan2
- AHDC1 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs138355578; ClinVar: benign; called by muse, mutect2, varscan2
- AHDC1 | c.2525C>T p.S842L | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs745569528; called by muse, mutect2, varscan2
- AHNAK | c.12768G>T p.K4256N | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV99946418; called by muse, mutect2, varscan2
- AHNAK2 | c.16729A>G p.I5577V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs1447472283; called by muse, mutect2, varscan2
- AHNAK2 | c.15700G>T p.E5234* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV60913634, COSV60922350; called by muse, mutect2, varscan2
- AHNAK2 | c.12795G>T p.E4265D | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.854); catalogued as COSV60931342; called by muse, mutect2, varscan2
- AHNAK2 | c.11650G>T p.G3884* | Nonsense Mutation (SNP) | VAF 67/174 reads (39%) | catalogued as rs765070678; called by muse, mutect2, varscan2
- AHNAK2 | c.6556G>A p.D2186N | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs760653505, COSV100317557; called by muse, mutect2, varscan2
- AHNAK2 | c.1346A>C p.E449A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs1299780946; called by muse, mutect2, varscan2
- AHRR | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as rs1342593288; called by muse, mutect2, varscan2
- AHSG | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV99889964; called by muse, mutect2
- AICDA | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57563759; called by muse, mutect2, varscan2
- AK2 | c.207C>T p.L69= (on ENST00000354858; = p.L111= on NM_001625.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/41 reads (24%) | catalogued as rs200433299; called by muse, mutect2, varscan2
- AKAP17A | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1298110241, COSV58311745; called by muse, mutect2, varscan2
- AKAP3 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57421384; called by muse, mutect2, varscan2
- AKAP3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs140648530; called by muse, mutect2, varscan2
- AKAP6 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766438234, COSV55208704; called by muse, mutect2, varscan2
- AKAP8L | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1047201066; called by muse, mutect2, varscan2
- AKAP9 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs758729015, COSV62344777; called by muse, varscan2
- AKAP9 | c.2328G>T p.E776D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV100662698; called by muse, mutect2, varscan2
- AKIRIN2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57636465; called by muse, mutect2, varscan2
- AKNAD1 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs745341212, COSV62196741; called by muse, mutect2, varscan2
- AKR1B10 | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs754791433; called by muse, mutect2, varscan2
- AKR1B15 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1347052560; called by muse, mutect2, varscan2
- AKR1C2 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV66332607; called by muse, mutect2, varscan2
- AL121899.2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757069005; called by muse, mutect2, varscan2
- AL136295.1 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758139805; called by muse, mutect2, varscan2
- AL441992.2 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs748843281; called by muse, mutect2, varscan2
- AL592490.1 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs1313291049, COSV69426707; called by muse, mutect2, varscan2
- AL592490.1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs954829851, COSV69424878; called by muse, mutect2, varscan2
- ALB | c.197T>C p.L66S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs1445650493; called by muse, mutect2, varscan2
- ALDH18A1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs199668897, COSV100973031; called by muse, mutect2, varscan2
- ALDH1A2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs563668428, COSV51081097; called by muse, mutect2, varscan2
- ALDH1B1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs201132163, COSV66620056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1L2 | c.2096C>A p.S699Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99310991; called by muse, mutect2, varscan2
- ALDH3B1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs780339479, COSV99141998; called by muse, varscan2
- ALDH3B1 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs748162494; called by muse, mutect2, varscan2
- ALDOA | c.938G>A p.R313H (on ENST00000642816 / NM_001243177.4; = p.R259H on NM_184041.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs750880048, COSV57632589; called by muse, mutect2, varscan2
- ALG10 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1278766456; called by muse, mutect2, varscan2
- ALG10B | c.1055G>T p.R352I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336579407; called by muse, varscan2
- ALG9 | c.1312G>A p.G438R (on ENST00000614444 / NM_001352418.1; = p.G445R on NM_024740.2) | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1392208402, COSV101211923; called by muse, mutect2, varscan2
- ALK | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs374135358, COSV101201808; called by muse, mutect2, varscan2
- ALKBH3 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs372711510; called by muse, mutect2, varscan2
- ALKBH4 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767584826; called by muse, mutect2, varscan2
- ALLC | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759353559, COSV52997783; called by muse, mutect2, varscan2
- ALMS1 | c.4351G>T p.E1451* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV52515532; called by muse, mutect2, varscan2
- ALOX12B | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs775449310, COSV59872873; called by muse, varscan2
- ALOX5AP | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV66857886; called by muse, mutect2, varscan2
- ALPK1 | c.2840C>A p.P947H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99453743; called by muse, mutect2, varscan2
- ALPK2 | c.3677G>T p.R1226I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV64498175; called by muse, mutect2, varscan2
- ALPK2 | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV100864195; called by muse, mutect2, varscan2
- AMBP | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 58/159 reads (36%) | catalogued as COSV54322390; called by muse, mutect2, varscan2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, mutect2, varscan2
- AMOT | c.2626G>A p.A876T (on ENST00000371959 / NM_001113490.1; = p.A467T on NM_133265.3) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1312082629, COSV59064561; called by muse, mutect2, varscan2
- AMOTL1 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.227); catalogued as rs1565387386; called by muse, mutect2, varscan2
- AMOTL2 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as rs745559796, COSV51438505; called by muse, mutect2, varscan2
- AMPD2 | c.2369A>G p.Y790C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV56646979; called by muse, mutect2, varscan2
- AMPH | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV57747686; called by muse, mutect2, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, varscan2
- AMY2B | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV100796357; called by muse, mutect2, varscan2
- ANGEL1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.148); catalogued as rs747699999, COSV51874440; called by muse, mutect2, varscan2
- ANGPT4 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as rs369053720; called by muse, mutect2, varscan2
- ANGPTL7 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs775409689, COSV100816141; called by muse, mutect2, varscan2
- ANK1 | c.3875C>T p.S1292F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs201033462; called by muse, mutect2, varscan2
- ANK2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1198719430, COSV52154113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.3970G>A p.V1324I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261943601, COSV52154963; called by muse, mutect2, varscan2
- ANK2 | c.5350C>T p.R1784* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV52147279; called by muse, mutect2, varscan2
- ANK3 | c.8696C>A p.S2899Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV55045136; called by muse, mutect2, varscan2
- ANK3 | c.4867C>T p.R1623* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV55058953; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANK3 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs967088925, COSV55045526, COSV99778108; called by muse, mutect2, varscan2
- ANK3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 39/91 reads (43%) | catalogued as COSV55079698; called by muse, mutect2, varscan2
- ANK3 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55073789; called by muse, mutect2, varscan2
- ANKAR | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs747944684, COSV104385734; called by muse, mutect2, varscan2
- ANKFN1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555939322, COSV59453904; called by muse, mutect2, varscan2
- ANKFN1 | c.2203G>T p.G735* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV59458258; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV51858541; called by muse, mutect2, varscan2
- ANKK1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746405597, COSV58273266, COSV58274845; called by muse, mutect2, varscan2
- ANKRD1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs866604612, COSV100865314; called by muse, mutect2, varscan2
- ANKRD11 | c.5587G>A p.D1863N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs769501359; called by muse, mutect2, varscan2
- ANKRD11 | c.2518C>T p.R840W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761259443, CD162073, COSV56363768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs751750670; called by muse, mutect2, varscan2
- ANKRD12 | c.2060G>A p.R687K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.432); catalogued as COSV100041105; called by muse, mutect2, varscan2
- ANKRD12 | c.4162C>A p.L1388I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV50819429, COSV50823705; called by muse, mutect2, varscan2
- ANKRD12 | c.5251C>A p.L1751I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.202); catalogued as COSV50819008; called by muse, mutect2, varscan2
- ANKRD13C | c.1218G>A p.P406= | Splice Region (SNP) | VAF 25/53 reads (47%) | catalogued as rs34209470; called by muse, mutect2, varscan2
- ANKRD30A | c.2125G>T p.E709* (on ENST00000611781; = p.E653* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs1180165839, COSV100654280; called by muse, mutect2, varscan2
- ANKRD30A | c.2445G>T p.Q815H (on ENST00000611781; = p.Q759H on NM_052997.2) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV64623796; called by mutect2, varscan2
- ANKRD34A | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs782733910; called by muse, mutect2, varscan2
- ANKRD35 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as rs368079050; called by muse, mutect2, varscan2
- ANKRD36B | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs2922568; called by muse, mutect2, varscan2
- ANKRD44 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as rs778147827, COSV56549225; called by mutect2, varscan2
- ANKRD44 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs754432821; called by muse, mutect2, varscan2
- ANKRD45 | c.237T>G p.N79K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100322453; called by muse, mutect2, varscan2
- ANKRD50 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.771); catalogued as rs757090928; called by muse, mutect2, varscan2
- ANO2 | c.2797G>A p.D933N (on ENST00000356134 / NM_001278597.3; = p.D937N on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs773059306, COSV59023842; called by muse, mutect2, varscan2
- ANO4 | c.1261C>A p.L421I (on ENST00000392977 / NM_001286615.2; = p.L386I on NM_178826.4) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.976); catalogued as COSV100152795; called by muse, mutect2, varscan2
- ANO7 | c.4C>T p.R2* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs778217816; called by muse, mutect2, varscan2
- ANOS1 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs192003597; called by muse, mutect2, varscan2
- ANOS1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52920288, COSV52926406; called by muse, mutect2, varscan2
- ANXA1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57411031; called by muse, mutect2, varscan2
- ANXA10 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100829075; called by muse, mutect2, varscan2
- ANXA11 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs961003614, COSV55416756; called by muse, mutect2, varscan2
- ANXA6 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs567378406; called by muse, varscan2
- ANXA8 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1325972402; called by muse, mutect2
- AOAH | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs769533119, COSV51741400, COSV51751152; called by muse, mutect2
- AOC2 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs765645252, COSV53825034; called by muse, mutect2, varscan2
- AOX1 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as rs140878478; called by muse, mutect2, varscan2
- AP002748.5 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV100568227; called by muse, mutect2, varscan2
- AP1S2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV57063747; called by muse, mutect2, varscan2
- AP4B1 | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV56723958; called by muse, mutect2, varscan2
- AP4E1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs556357549, COSV55916749; called by muse, mutect2, varscan2
- APAF1 | c.1886G>A p.R629K (on ENST00000551964 / NM_181861.2; = p.R618K on NM_001160.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.076); catalogued as rs1320897192; called by muse, mutect2, varscan2
- APAF1 | c.3040G>A p.D1014N (on ENST00000551964 / NM_181861.2; = p.D960N on NM_001160.3) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs745664662, COSV59662355; called by muse, varscan2
- APBA2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs145833994, COSV104435541; called by muse, mutect2
- APBA2 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67105258; called by muse, mutect2, varscan2
- APBB1 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV54976818; called by muse, varscan2
- APBB1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as rs749187223, COSV54977232; called by muse, mutect2, varscan2
- APC | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758069998, COSV57371119; called by muse, mutect2, varscan2
- APC | c.5189C>A p.S1730Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99072969; called by muse, varscan2
- APC2 | c.5216G>A p.R1739Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1174590149; called by muse, mutect2, varscan2
- APCS | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.078); catalogued as rs757884673; called by muse, mutect2, varscan2
- APEX1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs778999137, COSV51658617; called by muse, mutect2, varscan2
- APLF | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as rs1181554617; called by muse, mutect2, varscan2
- APLNR | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.603); catalogued as rs139313864; called by muse, mutect2, varscan2
- APLNR | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766255831; called by muse, mutect2, varscan2
- APLP1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs778308918, COSV55702037; called by muse, varscan2
- APOB | c.12890G>A p.R4297H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs375701380, CM138876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.9782C>A p.S3261Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51924560; called by muse, mutect2, varscan2
- APOB | c.9107C>A p.S3036Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925687; called by muse, mutect2, varscan2
- APOB | c.7610C>A p.S2537Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV51936053, COSV51953009; called by muse, mutect2, varscan2
- APOBEC3G | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs368187496; called by muse, mutect2, varscan2
- APOL3 | c.545G>T p.R182I (on ENST00000349314 / NM_145640.2; = p.R111I on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62580439; called by muse, mutect2, varscan2
- AQP3 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs749786864; called by muse, mutect2, varscan2
- AQP5 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52230869, COSV99527496; called by muse, mutect2, varscan2
- AQP9 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs752717219, COSV99583139; called by muse, mutect2, varscan2
- AQR | c.3656A>G p.Y1219C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773531382; called by muse, mutect2, varscan2
- ARAF | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51694113; called by muse, mutect2, varscan2
- ARAP2 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.803); catalogued as rs775209531, COSV58285497; called by muse, mutect2, varscan2
- ARAP2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV58285021; called by muse, mutect2, varscan2
- ARAP3 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs372101887, COSV53355287; called by muse, varscan2
- ARCN1 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs782274425, COSV104382303; called by muse, mutect2, varscan2
- AREL1 | c.471T>G p.I157M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV100707628; called by muse, mutect2, varscan2
- ARFGAP2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as rs1413666492, COSV53565507; called by muse, mutect2
- ARFGAP2 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.424); catalogued as COSV60300779; called by muse, mutect2, varscan2
- ARFIP2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1171308927; called by muse, mutect2, varscan2
- ARGLU1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs775108371, COSV100639795; called by muse, varscan2
- ARHGAP10 | c.2324G>T p.R775M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV60600963; called by muse, mutect2, varscan2
- ARHGAP20 | c.2588T>G p.I863S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs771614734; called by muse, mutect2, varscan2
- ARHGAP21 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV57605468; called by muse, varscan2
- ARHGAP28 | c.1030C>T p.R344C (on ENST00000383472 / NM_001366230.1; = p.R185C on NM_001010000.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as rs763511946, COSV99151273; called by muse, mutect2, varscan2
- ARHGAP29 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561134145, COSV53110916; called by muse, mutect2, varscan2
- ARHGAP30 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs763243355; called by muse, mutect2
- ARHGAP31 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV51792735; called by muse, mutect2, varscan2
- ARHGAP31 | c.3030C>A p.F1010L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51791065, COSV51801061; called by muse, mutect2, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ARHGAP45 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs918382275, COSV99565969; called by muse, mutect2, varscan2
- ARHGAP6 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100273319, COSV57293443; called by muse, mutect2, varscan2
- ARHGDIB | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs544170735, COSV57455377, COSV57455689; called by muse, varscan2
- ARHGEF10L | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51430321; called by muse, mutect2, varscan2
- ARHGEF11 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs200051467, COSV100168895; called by muse, mutect2, varscan2
- ARHGEF15 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1451448716; called by muse, mutect2, varscan2
- ARHGEF16 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs373186673; called by muse, mutect2, varscan2
- ARHGEF2 | c.1129C>T p.R377W (on ENST00000361247 / NM_001162383.2; = p.R349W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58112676; called by muse, mutect2, varscan2
- ARHGEF25 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as COSV54084216; called by muse, mutect2, varscan2
- ARHGEF26 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs776704269, COSV62846440; called by muse, mutect2, varscan2
- ARHGEF3 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs545739969, COSV56323415; called by muse, mutect2, varscan2
- ARHGEF35 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as rs1481832132; called by mutect2, varscan2
- ARHGEF4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV58125801; called by muse, mutect2, varscan2
- ARHGEF7 | c.2072G>A p.R691Q (on ENST00000375741 / NM_001113511.2; = p.R513Q on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749319662, COSV54551069; called by muse, mutect2, varscan2
- ARHGEF9 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.111); catalogued as rs374489713; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARID1A | c.6118G>A p.G2040R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs778665400; called by muse, mutect2, varscan2
- ARID2 | c.482T>C p.L161S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57608048; called by muse, mutect2, varscan2
- ARID2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1391481708, COSV57599514, COSV57605252; called by muse, mutect2, varscan2
- ARID2 | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs754489425; called by muse, mutect2, varscan2
- ARID3B | c.1367A>C p.N456T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1323655460; called by muse, mutect2, varscan2
- ARID3C | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52406214; called by muse, mutect2, varscan2
- ARID5B | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs550591609, COSV99688722; called by muse, mutect2, varscan2
- ARIH1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs1454157851; called by muse, mutect2, varscan2
- ARL13A | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV71448231; called by muse, mutect2, varscan2
- ARL13B | c.1118C>T p.T373M (on ENST00000394222 / NM_001174150.2; = p.T266M on NM_144996.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.558); catalogued as rs369850890; called by mutect2, varscan2
- ARL6IP6 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58443348; called by muse, mutect2, varscan2
- ARMC4 | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV53463043; called by muse, mutect2, varscan2
- ARMC8 | c.809G>A p.R270Q (on ENST00000469044 / NM_001363941.2; = p.R256Q on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs200770718; called by muse, mutect2, varscan2
- ARMC9 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100590168; called by muse, mutect2
- ARMCX5 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV55766047, COSV99863476; called by muse, mutect2, varscan2
- ARMCX5 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as COSV99863368; called by muse, mutect2, varscan2
- ARNT | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490240303, COSV100590925, COSV62229602; called by muse, mutect2, varscan2
- ARSB | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM003995; called by muse, mutect2, varscan2
- ARSH | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs777648295, COSV66963765; called by muse, mutect2, varscan2
- ARSK | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187543; called by muse, mutect2, varscan2
- ASAP1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs113796470; called by muse, varscan2
- ASB1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.887); catalogued as rs1559413492; called by muse, mutect2, varscan2
- ASB1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs370724967, COSV99223222; called by muse, mutect2, varscan2
- ASB17 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99407822; called by muse, mutect2, varscan2
- ASB4 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as rs769573705; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASGR2 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs201316903; called by muse, mutect2, varscan2
- ASH2L | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.345); catalogued as rs781543040, COSV51700030, COSV99167025; called by muse, mutect2, varscan2
- ASIC2 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1159022801; called by muse, mutect2, varscan2
- ASMTL | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs776878267, COSV67242719; called by muse, mutect2, varscan2
- ASNS | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV51553415; called by muse, varscan2
- ASNSD1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200381628, COSV53624312; called by muse, mutect2, varscan2
- ASPG | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs988442636; called by muse, mutect2, varscan2
- ASPM | c.9092G>A p.R3031Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs775344657; called by muse, mutect2, varscan2
- ASTL | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs765193573; called by muse, varscan2
- ASTN1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV56067894, COSV56075142; called by muse, mutect2, varscan2
- ASTN2 | c.1651C>T p.R551C (on ENST00000313400 / NM_001365069.1; = p.R500C on NM_014010.5) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776841753, COSV57773431; called by muse, mutect2, varscan2
- ASTN2 | c.1529T>C p.V510A (on ENST00000313400 / NM_001365069.1; = p.V459A on NM_014010.5) | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as rs1004005332; called by muse, mutect2, varscan2
- ASTN2 | c.1268G>A p.R423H (on ENST00000313400 / NM_001365069.1; = p.R372H on NM_014010.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as rs149596951; called by muse, mutect2, varscan2
- ASXL1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139716375, COSV60103020; called by muse, mutect2, varscan2
- ASXL1 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs147895689; called by muse, mutect2, varscan2
- ASXL3 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs765803411, COSV52471978, COSV52475965, COSV99324572; called by muse, mutect2, varscan2
- ASXL3 | c.3065C>A p.P1022H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52480999; called by muse, mutect2, varscan2
- ATAD2B | c.4265G>T p.R1422I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99478099; called by muse, mutect2, varscan2
- ATAD3A | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59232167; called by muse, mutect2, varscan2
- ATAD3B | c.331G>A p.E111K (on ENST00000308647; = p.E217K on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.31); catalogued as rs768804040; called by muse, mutect2, varscan2
- ATCAY | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755227202, COSV56655339; called by muse, mutect2, varscan2
- ATE1 | c.170G>T p.R57I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56444043; called by muse, mutect2, varscan2
- ATF2 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV51373547; called by muse, mutect2, varscan2
- ATF7 | c.1082G>A p.R361H (on ENST00000548446 / NM_001366555.2; = p.R350H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60642542; called by muse, mutect2, varscan2
- ATG10 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as rs139687676; called by muse, mutect2, varscan2
- ATG2A | c.5794C>T p.R1932C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390476568; called by muse, mutect2, varscan2
- ATG2A | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1174489270, COSV101034702; called by muse, mutect2, varscan2
- ATG2B | c.4261G>A p.D1421N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs376077529; called by muse, mutect2, varscan2
- ATG4A | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV58965065; called by muse, mutect2, varscan2
- ATM | c.3536C>A p.S1179Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV53735626, COSV53756873; called by muse, mutect2, varscan2
- ATM | c.7223C>T p.S2408L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs730881315, COSV53738904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs770940385, COSV63515656; called by muse, mutect2, varscan2
- ATP10B | c.3942C>A p.Y1314* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59150759; called by muse, mutect2, varscan2
- ATP11A | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs145335126; called by muse, mutect2, varscan2
- ATP11C | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758140991, COSV99047108; called by muse, mutect2, varscan2
- ATP11C | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as COSV100557651; called by muse, mutect2, varscan2
- ATP12A | c.2180T>C p.V727A | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54523989; called by muse, mutect2, varscan2
- ATP13A4 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55071924; called by muse, mutect2, varscan2
- ATP13A5 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.075); catalogued as COSV60869572; called by muse, mutect2, varscan2
- ATP1A4 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs766797631; called by muse, mutect2, varscan2
- ATP1B3 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.404); catalogued as rs777792091, COSV53951830; called by muse, varscan2
- ATP2A2 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as CD991623, CD991624; called by muse, mutect2, varscan2
- ATP2B1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs868096531, COSV53810259, COSV53813059; called by muse, mutect2, varscan2
- ATP2B2 | c.2863A>G p.I955V (on ENST00000352432; = p.I921V on NM_001683.5) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV100659744; called by muse, mutect2, varscan2
- ATP2B4 | c.2221G>T p.E741* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV100397760; called by muse, mutect2, varscan2
- ATP6AP2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1158279990; called by muse, varscan2
- ATP6V0A1 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1294855964; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2246C>T p.A749V (on ENST00000343619 / NM_001378531.1; = p.A743V on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1332649860; called by muse, varscan2
- ATP6V1B1 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199595604; called by muse, mutect2
- ATP7A | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58452268; called by muse, mutect2, varscan2
- ATP7A | c.2852C>T p.A951V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1557235725; called by muse, mutect2, varscan2
- ATP8A2 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54942662; called by muse, mutect2, varscan2
- ATP8A2 | c.2409G>T p.E803D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV54952564; called by muse, mutect2, varscan2
- ATP8A2 | c.2618A>G p.N873S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.163); catalogued as rs912933164; called by muse, mutect2, varscan2
- ATP8B2 | c.3392C>T p.T1131M (on ENST00000672630; = p.T1098M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs377129850; called by muse, mutect2, varscan2
- ATP8B4 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs773447978; called by muse, mutect2, varscan2
- ATP9B | c.1202T>G p.F401C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56954077; called by muse, mutect2, varscan2
- ATP9B | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs371010785; called by mutect2, varscan2
- ATP9B | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV56946532; called by muse, mutect2, varscan2
- ATR | c.6208C>A p.L2070I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV63388224; called by muse, mutect2, varscan2
- ATRN | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs748307870, COSV53523166; called by muse, mutect2, varscan2
- ATRN | c.3949C>A p.L1317I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as rs1420426816; called by muse, mutect2, varscan2
- ATRNL1 | c.1742G>T p.R581I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61808835; called by muse, mutect2, varscan2
- ATRNL1 | c.2882G>A p.C961Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100370253, COSV58089644; called by muse, mutect2, varscan2
- ATRX | c.6235C>T p.R2079* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV64877507; called by muse, mutect2, varscan2
- ATRX | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64871810, COSV64872548; called by muse, mutect2, varscan2
- ATRX | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs367986587, COSV100971295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV64882284; called by muse, mutect2, varscan2
- ATXN7L2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs948944236; called by muse, mutect2, varscan2
- AUH | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs529693736, COSV57861958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AURKC | c.368C>A p.A123D (on ENST00000302804 / NM_001015878.2; = p.A89D on NM_003160.3) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774633250; called by muse, mutect2, varscan2
- AWAT1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs766687052, COSV65738218; called by muse, mutect2, varscan2
- AXIN1 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs755020386; called by muse, mutect2, varscan2
- AXL | c.1862C>A p.P621H (on ENST00000301178 / NM_021913.5; = p.P612H on NM_001699.6) | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56573258; called by muse, varscan2
- AZU1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201652896, COSV52141841; called by muse, mutect2, varscan2
- B3GALNT2 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV100010701; called by muse, mutect2, varscan2
- B3GALT1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422932467; called by muse, mutect2, varscan2
- B3GALT5 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs969527149, COSV58197718; called by muse, mutect2, varscan2
- B3GAT1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs367583989, COSV100437896; called by muse, mutect2, varscan2
- B3GLCT | c.345G>A p.P115= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as rs780553393; called by muse, mutect2, varscan2
- B3GNT7 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs757654927, COSV55006274; called by muse, mutect2, varscan2
- B3GNT7 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs781512981, COSV55006299; called by muse, varscan2
- B4GALNT1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs765536804, COSV57542116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B4GALNT1 | c.493C>T p.L165= | Splice Region (SNP) | VAF 31/95 reads (33%) | catalogued as rs764218980; called by muse, mutect2, varscan2
- B4GALNT1 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV62041658; called by muse, mutect2, varscan2
- B4GALNT1 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs1359670563; called by muse, mutect2
- B4GALT7 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs753374573, COSV50353384; called by muse, mutect2, varscan2
- BABAM2 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764086199; called by muse, mutect2, varscan2
- BACH1 | c.332A>C p.E111A | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs762029576; called by muse, mutect2, varscan2
- BACH1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1257840097, COSV54517914; called by muse, mutect2, varscan2
- BACH1 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104379582; called by muse, mutect2, varscan2
- BAIAP3 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs771761904; called by muse, mutect2, varscan2
- BANF2 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773946149; called by muse, mutect2, varscan2
- BANK1 | c.2171A>G p.D724G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1454010016; called by muse, mutect2, varscan2
- BANP | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.97); catalogued as rs1243700629; called by muse, mutect2, varscan2
- BARX2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769021373, COSV55650354; called by muse, mutect2, varscan2
- BAZ1B | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782111334, COSV59990788; called by muse, varscan2
- BAZ1B | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV59994530; called by muse, mutect2, varscan2
- BAZ2B | c.6461G>T p.R2154M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58597169; called by muse, mutect2, varscan2
- BAZ2B | c.4684C>A p.L1562I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58595224, COSV58600037; called by mutect2, varscan2
- BAZ2B | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs764609647, COSV58609868; called by muse, mutect2, varscan2
- BAZ2B | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1434510372; called by muse, mutect2, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, mutect2, varscan2
- BCAM | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as rs751493122; called by muse, mutect2, varscan2
- BCAP31 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs372317882, COSV61451335; called by muse, mutect2, varscan2
- BCAS3 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1184319232, COSV66772554; called by muse, mutect2, varscan2
- BCAS3 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779645653; called by muse, mutect2, varscan2
- BCAS4 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as COSV52811159; called by muse, mutect2, varscan2
- BCKDK | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1415332096; called by muse, mutect2, varscan2
- BCL11B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.387); catalogued as rs1359029879; called by muse, mutect2, varscan2
- BCL2L11 | c.481G>A p.A161T (on ENST00000393256 / NM_138621.5; = p.A101T on NM_006538.5) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs757046249, COSV100427445; called by muse, varscan2
- BCL6 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1218233420, COSV51651047; called by muse, mutect2, varscan2
- BCLAF1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.133); catalogued as rs369285091; called by muse, mutect2, varscan2
- BCLAF3 | c.1936G>T p.V646L (on ENST00000379682 / NM_001367774.1; = p.V617L on NM_198279.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs771945174; called by muse, mutect2, varscan2
- BCOR | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs923387791, COSV60708308; called by muse, mutect2, varscan2
- BCOR | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs866627719, COSV60701219, COSV60703371; called by muse, mutect2, varscan2
- BCOR | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs745470688, COSV60715608; called by muse, mutect2, varscan2
- BCORL1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1326601919; called by muse, mutect2, varscan2
- BCR | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs760803745; called by muse, varscan2
- BECN1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769533035; called by muse, mutect2, varscan2
- BEND2 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV66215344; called by muse, mutect2, varscan2
- BEND2 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV66215446; called by muse, mutect2, varscan2
- BEND2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs770529341, COSV66217323; called by muse, mutect2, varscan2
- BEND7 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs534620750, COSV100346581; called by muse, mutect2, varscan2
- BEX1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV65579974; called by muse, mutect2, varscan2
- BFSP2 | c.732T>C p.D244= | Splice Region (SNP) | VAF 18/72 reads (25%) | catalogued as rs1307042469; called by muse, varscan2
- BGN | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV100525175, COSV59035987; called by muse, mutect2, varscan2
- BGN | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933381952, COSV59036240; called by muse, mutect2, varscan2
- BHLHE22 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100417684; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2, varscan2
- BID | c.409G>A p.A137T (on ENST00000317361 / NM_197966.2; = p.A91T on NM_001196.4) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs375433200; called by muse, mutect2, varscan2
- BIK | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs532663391, COSV51792892, COSV51794081; called by muse, mutect2, varscan2
- BIRC2 | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV57162758; called by muse, mutect2, varscan2
- BIRC6 | c.2523G>T p.E841D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs969024650; called by muse, varscan2
- BIRC6 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772811050, COSV101427959; called by muse, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2
- BIRC7 | c.869G>A p.R290H (on ENST00000217169 / NM_139317.3; = p.R272H on NM_022161.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs749536114; called by muse, mutect2, varscan2
- BLM | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs773952896; called by muse, mutect2, varscan2
- BLVRA | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs754440828, COSV55516258; called by muse, mutect2, varscan2
- BMERB1 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs757365966, COSV55509794; called by muse, varscan2
- BMP3 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51082849; called by muse, mutect2, varscan2
- BMP4 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs1225147273; called by muse, mutect2, varscan2
- BMP5 | c.710C>G p.T237R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV100895880; called by muse, mutect2, varscan2
- BMP5 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100896475; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMP7 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs767991677, COSV101216309; called by muse, mutect2, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BNIP5 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as rs141030977; called by muse, mutect2, varscan2
- BOD1L1 | c.8908C>T p.R2970C | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs775550481, COSV50068860; called by muse, mutect2, varscan2
- BOD1L1 | c.7037G>T p.R2346I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV50011878; called by muse, mutect2, varscan2
- BOD1L1 | c.348C>A p.N116K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368418760, COSV50014512; called by muse, mutect2, varscan2
- BOLA3 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs941523861; called by muse, mutect2, varscan2
- BOLL | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as rs915401766, COSV99987427; called by muse, mutect2, varscan2
- BPGM | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs150724691, COSV104421065; called by muse, mutect2, varscan2
- BPIFB6 | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as COSV62755959; called by muse, mutect2, varscan2
- BPIFC | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs1189647948; called by muse, mutect2, varscan2
- BRCA2 | c.1996A>C p.I666L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as COSV66456678; called by muse, mutect2, varscan2
- BRCC3 | c.680T>G p.V227G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.437); catalogued as COSV100341571, COSV57463042; called by muse, mutect2, varscan2
- BRD1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs755515102, COSV53457186; called by muse, mutect2, varscan2
- BRD1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53460331, COSV99048785; called by muse, mutect2, varscan2
- BRD3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs775918544, COSV57701452; called by muse, mutect2, varscan2
- BRD4 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99650731; called by muse, mutect2, varscan2
- BRD7 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as rs769621117, COSV67158819; called by muse, mutect2, varscan2
- BRD9 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs757335221; called by muse, mutect2, varscan2
- BRF1 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV59269677; called by muse, mutect2, varscan2
- BRINP1 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs764781191, COSV99774976; called by muse, mutect2, varscan2
- BRINP3 | c.1498C>A p.L500M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100819409; called by muse, varscan2
- BRINP3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs147790033, COSV66520603; called by muse, mutect2, varscan2
- BRINP3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs765103774, COSV66523080; called by muse, mutect2, varscan2
- BROX | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372955065; called by muse, mutect2, varscan2
- BRS3 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs144381228; called by mutect2, varscan2
- BRWD3 | c.1407C>A p.F469L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64751328, COSV64752124; called by muse, mutect2, varscan2
- BSN | c.5651C>T p.A1884V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs780839026, COSV56530475; called by muse, mutect2, varscan2
- BSN | c.9896G>A p.R3299H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs775913857, COSV56513683; called by muse, mutect2, varscan2
- BST1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs750782710; called by muse, mutect2, varscan2
- BTAF1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV56434141; called by muse, mutect2, varscan2
- BTAF1 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs375243421; called by muse, mutect2, varscan2
- BTBD10 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99534000; called by muse, mutect2, varscan2
- BTBD3 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.987); catalogued as rs750419351, COSV54781054; called by muse, mutect2, varscan2
- BTG1 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV55460912; called by muse, varscan2
- BTN1A1 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs763405584; called by muse, mutect2, varscan2
- BTN1A1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV99764322; called by muse, mutect2, varscan2
- BTN3A3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1028608102; called by muse, mutect2, varscan2
- BTN3A3 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs988992246; called by muse, mutect2, varscan2
- BTNL8 | c.859G>A p.A287T (on ENST00000340184 / NM_001040462.3; = p.R330H on NM_024850.2) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs768102519, COSV51460840; called by muse, mutect2, varscan2
- BUB1 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV57061016; called by muse, mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2, varscan2
- C11orf65 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373726941; called by mutect2, varscan2
- C12orf4 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778809161; called by muse, mutect2, varscan2
- C12orf42 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.957); catalogued as COSV59380203; called by muse, mutect2
- C12orf50 | c.480A>C p.E160D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53897575; called by muse, mutect2, varscan2
- C15orf39 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs780644935; called by muse, mutect2, varscan2
- C16orf54 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.51); catalogued as rs747945510, COSV61477091; called by muse, mutect2, varscan2
- C16orf70 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54627392; called by muse, mutect2, varscan2
- C16orf72 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV100589121; called by muse, mutect2, varscan2
- C18orf25 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs62096535, COSV56364852; called by muse, mutect2, varscan2
- C18orf54 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100266671; called by muse, mutect2, varscan2
- C19orf47 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751821059; called by muse, mutect2, varscan2
- C1S | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV100196307; called by muse, varscan2
- C1S | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.19); catalogued as rs148512159, COSV61071990; called by muse, varscan2
- C1orf116 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs140606489; called by muse, mutect2, varscan2
- C1orf116 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.693); catalogued as rs706846; called by muse, mutect2, varscan2
- C1orf216 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323158016, COSV52046335; called by muse, mutect2, varscan2
- C2 | c.1455+2T>C p.X485_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as rs761681406, COSV100191127; called by muse, mutect2, varscan2
- C20orf194 | c.3244C>T p.R1082W | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs772723594, COSV52690791; called by muse, mutect2, varscan2
- C2CD5 | c.2275T>C p.Y759H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV61725596; called by muse, mutect2
- C2orf16 | c.4915C>T p.R1639C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1426537450, COSV62675332; called by muse, mutect2, varscan2
- C3 | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs772142244, COSV55575021, COSV99836202; called by muse, mutect2, varscan2
- C3orf14 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs750980777; called by muse, varscan2
- C3orf18 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.035); catalogued as rs769002907; called by muse, mutect2, varscan2
- C3orf22 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100559512; called by muse, mutect2, varscan2
- C4BPB | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as rs1346400975, COSV99699796; called by muse, mutect2, varscan2
- C5AR2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs754044936; called by muse, mutect2, varscan2
- C6orf120 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377593831; called by muse, mutect2, varscan2
- C6orf89 | c.711C>G p.N237K (on ENST00000373685; = p.N244K on NM_152734.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748021103; called by muse, mutect2, varscan2
- C7orf61 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs745459414, COSV100190271; called by muse, mutect2, varscan2
- C8A | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772455324, COSV63485646; called by muse, mutect2, varscan2
- C8A | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559111946, COSV63483217; called by muse, mutect2, varscan2
- C8orf82 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1169251869; called by muse, mutect2, varscan2
- C9orf135 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.061); catalogued as rs374542595; called by muse, mutect2, varscan2
- C9orf152 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs763276912, COSV68762752; called by muse, mutect2, varscan2
- C9orf43 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99928344; called by muse, mutect2, varscan2
- CA2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs765669662, COSV53406184; called by muse, mutect2, varscan2
- CA3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759873251, COSV53410509; called by muse, mutect2, varscan2
- CA3 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs746057618; called by muse, mutect2, varscan2
- CAB39L | c.638_639del p.Y213* | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1187642830; called by mutect2, pindel, varscan2
- CABIN1 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV54081344; called by muse, mutect2, varscan2
- CABIN1 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99572482; called by muse, mutect2, varscan2
- CABP2 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1871035; called by muse, varscan2
- CABP7 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765114031; called by muse, mutect2, varscan2
- CACHD1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1235538167, COSV51557130, COSV51562484; called by muse, mutect2, varscan2
- CACNA1A | c.6385C>T p.R2129C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1255940553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.5983C>T p.R1995C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs903596182; called by muse, mutect2, varscan2
- CACNA1B | c.6394C>T p.R2132C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs952939628; called by muse, mutect2, varscan2
- CACNA1C | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.122); catalogued as rs369483452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59699996; called by muse, mutect2, varscan2
- CACNA1C | c.5320G>A p.A1774T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.086); catalogued as rs767425352, COSV59736148; called by muse, mutect2, varscan2
- CACNA1E | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs780358424; called by muse, mutect2, varscan2
- CACNA1E | c.3581C>T p.T1194M | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1351471209, COSV100702887, COSV62404131; called by muse, mutect2, varscan2
- CACNA1F | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs144099880; called by muse, mutect2
- CACNA1G | c.3914C>A p.A1305D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100662767; called by muse, mutect2, varscan2
- CACNA1H | c.3805C>T p.R1269C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs779802120, COSV100672763; called by muse, mutect2, varscan2
- CACNA1H | c.6208C>T p.R2070C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs758461760, COSV52355028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359414; called by muse, mutect2, varscan2
- CACNA1S | c.2920G>A p.V974M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); catalogued as rs757840865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 58/79 reads (73%) | catalogued as rs1553898213, COSV55549370; called by muse, mutect2, varscan2
- CACNB1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs781727961; called by muse, varscan2
- CACNB3 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs770339764; called by muse, mutect2, varscan2
- CACNG3 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV50070934; called by muse, mutect2, varscan2
- CACNG7 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1310679798, COSV55814371, COSV55817430; called by muse, mutect2, varscan2
- CACTIN | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs752325115, COSV50272181; called by muse, mutect2, varscan2
- CACYBP | c.231T>G p.N77K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62881623; called by muse, mutect2, varscan2
- CAD | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs1442684373, COSV99255527; called by muse, mutect2, varscan2
- CADM3 | c.236G>A p.R79Q (on ENST00000368125 / NM_001127173.3; = p.R113Q on NM_021189.5) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63687904; called by muse, varscan2
- CADPS | c.2872C>A p.L958I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV51886329; called by muse, varscan2
- CADPS2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs746180204; called by muse, mutect2, varscan2
- CALCOCO2 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs778991486; called by muse, mutect2, varscan2
- CALCR | c.859C>A p.L287M (on ENST00000649521 / NM_001164737.2; = p.L271M on NM_001742.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV64011257; called by muse, mutect2, varscan2
- CALD1 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV62655167; called by muse, mutect2
- CAMLG | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs188626944; called by muse, mutect2, varscan2
- CAMP | c.431A>G p.K144R (on ENST00000296435; = p.K141R on NM_004345.5) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.066); catalogued as COSV99601216; called by muse, mutect2, varscan2
- CAMTA2 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100742001; called by muse, mutect2, varscan2
- CAND2 | c.1466G>A p.R489H (on ENST00000456430 / NM_001162499.2; = p.R396H on NM_012298.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1375841662; called by muse, mutect2, varscan2
- CAP2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201321988, COSV57731423; called by muse, mutect2, varscan2
- CAPN10 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1274186175, COSV99550269; called by muse, mutect2, varscan2
- CAPN3 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); catalogued as rs768426565, CM051861, CM053160, COSV58820489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN5 | c.1616G>A p.R539H (on ENST00000456580; = p.R499H on NM_004055.5) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs140490506; called by muse, mutect2, varscan2
- CAPNS1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs866083785; called by muse, mutect2, varscan2
- CAPRIN1 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs1405472982; called by muse, mutect2, varscan2
- CAPRIN2 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs149926848; called by muse, mutect2, varscan2
- CARD10 | c.3016G>A p.G1006S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as rs1008908544, COSV99325400; called by muse, mutect2
- CARD11 | c.2879T>G p.L960R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67801154; called by muse, mutect2, varscan2
- CARD11 | c.1188C>A p.C396* | Nonsense Mutation (SNP) | VAF 43/113 reads (38%) | catalogued as COSV67797421; called by muse, mutect2, varscan2
- CARD16 | c.365G>T p.R122M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100995115; called by muse, varscan2
- CARD17 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs751666071; called by mutect2, varscan2
- CARD18 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV101596042; called by muse, varscan2
- CARD8 | c.411G>T p.E137D (on ENST00000651546 / NM_001184900.3; = p.E87D on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs765521296, COSV62873952; called by muse, mutect2, varscan2
- CARMIL3 | c.2399C>T p.A800V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs774345899, COSV57728187; called by muse, varscan2
- CASP1 | c.1120C>T p.R374* (on ENST00000436863 / NM_033292.4; = p.R353* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs750821528, COSV52832044; called by muse, varscan2
- CASP1 | c.830C>T p.P277L (on ENST00000436863 / NM_033292.4; = p.P256L on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765350445, COSV100782862, COSV62056177; called by muse, mutect2, varscan2
- CASP3 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs567223280, COSV57725046; called by muse, mutect2, varscan2
- CASP4 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 58/152 reads (38%) | catalogued as rs1219592466; called by muse, varscan2
- CASP6 | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV54460418; called by muse, mutect2, varscan2
- CASP8 | c.775G>T p.D259Y (on ENST00000432109 / NM_033355.3; = p.D276Y on NM_001228.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV51851780; called by muse, mutect2, varscan2
- CASQ1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs764998802; called by muse, mutect2, varscan2
- CASR | c.2438G>A p.R813H (on ENST00000490131; = p.R890H on NM_000388.4) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as rs567996888, COSV56142012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASS4 | c.1788G>T p.E596D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.136); catalogued as COSV100824655; called by muse, mutect2, varscan2
- CASZ1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as rs774931477; called by muse, mutect2, varscan2
- CAT | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769313918, COSV99573369; called by muse, mutect2, varscan2
- CATSPER2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs751517231, COSV58660797; called by muse, mutect2, varscan2
- CATSPERB | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV99831168; called by muse, mutect2, varscan2
- CATSPERD | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs201591484; called by muse, mutect2, varscan2
- CATSPERD | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV100487016; called by muse, mutect2, varscan2
- CBARP | c.607G>A p.E203K (on ENST00000382477; = p.E183K on NM_152769.3) | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767366962; called by muse, mutect2, varscan2
- CBLB | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs990086709, COSV51428844; called by muse, mutect2, varscan2
- CBLB | c.804A>C p.E268D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV51430910; called by muse, mutect2, varscan2
- CBLL2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV60369355; called by muse, varscan2
- CBR1 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV51739446; called by muse, mutect2, varscan2
- CC2D2A | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs543650388, COSV67502578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCBE1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.792); catalogued as rs115699870; called by muse, mutect2, varscan2
- CCDC102B | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100101711; called by muse, mutect2, varscan2
- CCDC105 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as rs957447707, COSV52965632; called by muse, mutect2, varscan2
- CCDC105 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs868512122; called by muse, mutect2, varscan2
- CCDC107 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs202093963; called by muse, mutect2, varscan2
- CCDC110 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56873442; called by muse, mutect2, varscan2
- CCDC115 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as rs772966334, COSV99383777; called by muse, mutect2, varscan2
- CCDC116 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747066746, COSV53037139; called by muse, mutect2
- CCDC136 | c.2993A>C p.K998T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs779866057; called by muse, mutect2, varscan2
14,448 further variants in this file (10,653 protein-altering or splice-affecting, 3,407 silent, 388 other) are not listed here.
